Surgical pathology report (de-identified scan), TCGA case TCGA-DB-A64P, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DB-A64P-01A (Primary Tumor).

[page 1 of 2]
Final Diagnosis:

A-C. Brain, left frontal masses #1-#3 and CUSA, resection: Oligodendroglioma with early anaplastic transformation (WHO grade III).

Immunohistochemical stains were performed on paraffin embedded tissue using antibodies to IDH1 (R132H), p53 and Ki67. Neoplastic cells are positive with antibodies to IDH1 (R132H) consistent with IDH1 mutation. p53 protein is positive in scattered cells. Ki67 labeling index varies from low to moderate. The findings support the above diagnosis.

Fluorescence in situ hybridization (FISH) studies for 1p19q deletion have been ordered on paraffin sections and will be performed by the
For interpretation, see

Transcribed by:

Preliminary Frozen Section Consultation:

A-B. Brain, left frontal masses #1-#2, smears: Diffuse glioma, favor astrocytoma. Hold over for final typing and

continued next page Page 1 of 2

ICD 0-3
Oligodendroglioma,
anaplastic 9451/3
Site L^{path} Brain, frontal
lobe C71.1
C6CF
Brain, supratentorial
C71.0
JW 5/10/13

[page 2 of 2]
grading.

Intraoperative cytologic smear(s) interpretation performed by:

Gross Description:

A. Received fresh labeled "left frontal brain mass" is a 3.2 x 2.6 x 2.0 cm portion of brain. Smears prepared. All submitted. Grossed by

B. Received fresh labeled "#2 left frontal brain mass" is a 3.2 x 2.0 x 1.5 cm portion of brain. Smears prepared. All submitted. Grossed by

C. Received fresh within a trap labeled "CUSA specimen trap - left frontal brain mass" is a 4.1 x 4.0 x 0.8 cm aggregate of brain. All submitted. Grossed by

Block Summary:

Part A: Left frontal brain mass

- 1 Lt frontal brain mass 1
- 2 Lt frontal brain mass 2
- 3 Lt frontal brain mass 3
- 4 Lt frontal brain mass 4
- 5 Lt frontal brain mass 5
- 6 Lt frontal brain mass 6
- 7 Lt frontal brain mass 7

Part B: #2 left frontal brain mass

- 1 Lt frontal brain mass #2-1
- 2 Lt frontal brain mass #2-2
- 3 Lt frontal brain mass #2-3
- 4 Lt frontal brain mass #2-4
- 5 Lt frontal brain mass #2-5

Part C: specimen trap - left frontal brain mass

- 1 trap Lt frontal 1
- 2 trap Lt frontal 2
- 3 trap Lt frontal 3
- 4 trap Lt frontal 4
- 5 trap Lt frontal 5

END OF REPORT

Page 2 of 2

Discrepancy Synchronous Primary Noted		☒

Source: NCI Genomic Data Commons file b6dceafb-3904-4c0a-b09c-2a9a8750e310 (TCGA-DB-A64P.3D2EEE2E-B4EB-4603-B4D2-AA4B0F790200.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).